Somatic mutation profile of tumor specimen C3N-01653-03 (aliquot CPT0380840009) from CPTAC case C3N-01653, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G4; Age at diagnosis: 58.4 years (21,323 days).
Specimen C3N-01653-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3e9e23cd-7bd0-49cd-bde2-e1ce292bbc22.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01653-31 (Blood Derived Normal), aliquot CPT0381130002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f46fd84d-ae78-4ac0-952e-99363388ecab

The open-access MAF lists 139 somatic variants for this specimen: 98 protein-altering or splice-affecting, 23 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 79, Silent 23, Intron 7, In Frame Del 5, Frame Shift Del 4, Nonsense Mutation 3, 5'UTR 3, 3'Flank 3, Splice Site 3, Translation Start Site 2, 3'UTR 2, 5'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AFAP1L2 | c.431C>T p.S144F | Missense Mutation (SNP) | VAF 73/306 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1447786906; called by muse, mutect2, varscan2
- ANKRD35 | c.169C>T p.P57S | Missense Mutation (SNP) | VAF 43/86 reads (50%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.868); catalogued as rs782294282, COSV62909730; called by muse, mutect2, varscan2
- ATP6V0A1 | c.398G>A p.R133H | Missense Mutation (SNP) | VAF 25/166 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.141); catalogued as rs1269274593, COSV52876336, COSV52878190; called by muse, mutect2, varscan2
- CDRT1 | c.2137G>T p.A713S | Missense Mutation (SNP) | VAF 24/172 reads (14%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.071); catalogued as rs760464700; called by muse, mutect2, varscan2
- CHTOP | c.559C>T p.R187W | Missense Mutation (SNP) | VAF 177/364 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs147496068; called by muse, mutect2, varscan2
- CYP4B1 | c.349T>G p.F117V | Missense Mutation (SNP) | VAF 43/243 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.363); catalogued as COSV54721150; called by muse, mutect2, varscan2
- GGTLC1 | c.442G>A p.G148S | Missense Mutation (SNP) | VAF 136/666 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.164); catalogued as rs780640505; called by muse, mutect2, varscan2
- KITLG | c.398G>C p.R133T | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT tolerated (0.47); PolyPhen benign (0.323); catalogued as COSV57202357; called by muse, mutect2, varscan2
- LAMA5 | c.6654G>C p.Q2218H | Missense Mutation (SNP) | VAF 52/262 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0.014); catalogued as rs1426701899; called by muse, mutect2, varscan2
- LETM1 | c.1058G>C p.R353P | Missense Mutation (SNP) | VAF 55/272 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100245536; called by muse, mutect2, varscan2
- MATN2 | c.1432G>C p.D478H | Missense Mutation (SNP) | VAF 36/203 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1169120068; called by muse, mutect2, varscan2
- MYH3 | c.3373G>A p.A1125T | Missense Mutation (SNP) | VAF 49/180 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.861); catalogued as COSV56862221; called by muse, mutect2, varscan2
- MYO1E | c.1130A>G p.K377R | Missense Mutation (SNP) | VAF 89/332 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.445); catalogued as rs761323040; called by muse, mutect2, varscan2
- OR52N1 | c.466A>G p.M156V | Missense Mutation (SNP) | VAF 77/372 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV100398650; called by muse, mutect2, varscan2
- OR56A4 | c.676G>T p.G226* | Nonsense Mutation (SNP) | VAF 52/339 reads (15%) | catalogued as COSV100417638; called by muse, mutect2, varscan2
- PBRM1 | c.3979G>T p.E1327* (on ENST00000296302 / NM_001366071.2; = p.E1302* on NM_018313.5) | Nonsense Mutation (SNP) | VAF 43/152 reads (28%) | catalogued as COSV56298518, COSV56298992; called by muse, mutect2, varscan2
- PIK3C2B | c.2491C>G p.L831V | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100916279; called by muse, mutect2
- PROB1 | c.868G>T p.V290L | Missense Mutation (SNP) | VAF 10/282 reads (4%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.147); catalogued as COSV104402419; called by muse, mutect2
- RSRC1 | c.988G>A p.G330S | Missense Mutation (SNP) | VAF 25/150 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as COSV99907189; called by muse, mutect2, varscan2
- SECISBP2 | c.1394C>G p.S465C | Missense Mutation (SNP) | VAF 25/241 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as COSV60529367; called by muse, mutect2, varscan2
- SHANK1 | c.4300C>T p.P1434S | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs763365954, COSV53245129; called by muse, mutect2, varscan2
- SPATA16 | c.407G>A p.R136H | Missense Mutation (SNP) | VAF 137/372 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.201); catalogued as rs185789602, COSV63533630; called by muse, mutect2, varscan2
- SYTL4 | c.430C>T p.P144S | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.021); catalogued as rs908392026; called by muse, mutect2, varscan2
- TRMT112 | c.338T>C p.I113T | Missense Mutation (SNP) | VAF 42/212 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV50005590; called by muse, mutect2, varscan2
- UGP2 | c.722G>A p.G241E | Missense Mutation (SNP) | VAF 37/200 reads (19%) | SIFT tolerated (0.93); PolyPhen benign (0.003); catalogued as rs148522627; called by muse, mutect2, varscan2
- VPS35 | c.2212-1G>C p.X738_splice | Splice Site (SNP) | VAF 28/148 reads (19%) | catalogued as COSV100140834; called by muse, mutect2, varscan2
- WDR72 | c.712-1G>A p.X238_splice | Splice Site (SNP) | VAF 21/184 reads (11%) | catalogued as rs1567042786, COSV64741069, COSV64755086; called by muse, mutect2
- ZNF724 | c.506C>T p.P169L | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.025); catalogued as rs1341448102; called by muse, mutect2, varscan2
- ACTR5 | c.70G>A p.V24M | Missense Mutation (SNP) | VAF 119/640 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- ADAM19 | c.53A>C p.Q18P | Missense Mutation (SNP) | VAF 20/240 reads (8%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); called by muse, mutect2
- ADAMTS18 | c.2426C>A p.P809H | Missense Mutation (SNP) | VAF 117/531 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADGRV1 | c.8364T>G p.I2788M | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- ADSL | c.357+6C>G | Splice Region (SNP) | VAF 34/194 reads (18%) | called by muse, mutect2, varscan2
- AKT2 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 111/488 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- APOB | c.2673T>G p.I891M | Missense Mutation (SNP) | VAF 78/278 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- ARMC4 | c.1926G>C p.K642N | Missense Mutation (SNP) | VAF 60/337 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- ATP6V1E1 | c.276+2T>A p.X92_splice | Splice Site (SNP) | VAF 24/78 reads (31%) | called by muse, mutect2, varscan2
- BBX | c.2782G>A p.E928K (on ENST00000325805 / NM_001142568.3; = p.E898K on NM_020235.7) | Missense Mutation (SNP) | VAF 73/150 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- BFAR | c.227A>C p.K76T | Missense Mutation (SNP) | VAF 29/196 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CDH22 | c.1096G>A p.D366N | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.656); called by muse, mutect2
- CDK13 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 22/66 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- CEP135 | c.1478A>T p.D493V | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.013); called by muse, varscan2
- CHD1 | c.371A>T p.E124V | Missense Mutation (SNP) | VAF 71/281 reads (25%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.245); called by muse, mutect2, varscan2
- CLCC1 | c.293_307del p.R98_N102del | In Frame Del (DEL) | VAF 6/46 reads (13%) | called by mutect2, pindel
- CPXM2 | c.168del p.F57Sfs*54 | Frame Shift Del (DEL) | VAF 31/206 reads (15%) | called by mutect2, pindel, varscan2
- CRACD | c.1276T>G p.F426V | Missense Mutation (SNP) | VAF 57/298 reads (19%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- CTCFL | c.1988dup p.*664Vfs*18 | Frame Shift Ins (INS) | VAF 38/110 reads (35%) | called by mutect2, pindel
- DNAH3 | c.9232T>A p.W3078R | Missense Mutation (SNP) | VAF 21/122 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- DNAH6 | c.4483G>C p.V1495L | Missense Mutation (SNP) | VAF 24/144 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAH9 | c.3956G>T p.W1319L | Missense Mutation (SNP) | VAF 40/228 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FCGBP | c.6490C>A p.L2164M | Missense Mutation (SNP) | VAF 123/1216 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.627); called by muse, mutect2, varscan2
- FRRS1 | c.1846G>A p.E616K | Missense Mutation (SNP) | VAF 52/217 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- FUCA1 | c.1201C>T p.H401Y | Missense Mutation (SNP) | VAF 53/276 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- GGA3 | c.335C>A p.T112N (on ENST00000537686 / NM_138619.4; = p.T79N on NM_014001.5) | Missense Mutation (SNP) | VAF 38/173 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- GOLGA6L10 | c.1417A>C p.M473L | Missense Mutation (SNP) | VAF 64/2436 reads (3%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); called by muse, mutect2
- HMGCLL1 | c.929G>C p.G310A | Missense Mutation (SNP) | VAF 21/131 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- HUWE1 | c.6866A>G p.N2289S | Missense Mutation (SNP) | VAF 59/149 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IPO11 | c.2705A>T p.E902V | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- ITGAL | c.2024T>C p.L675P | Missense Mutation (SNP) | VAF 30/243 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ITGAM | c.1927G>T p.V643L (on ENST00000648685 / NM_001145808.2; = p.V642L on NM_000632.4) | Missense Mutation (SNP) | VAF 43/249 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ITPR1 | c.1669T>C p.Y557H (on ENST00000354582; = p.Y542H on NM_002222.7) | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- KIF27 | c.818C>T p.A273V | Missense Mutation (SNP) | VAF 18/178 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- KRBA2 | c.634A>T p.M212L | Missense Mutation (SNP) | VAF 65/240 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- LRIF1 | c.488T>C p.I163T | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- M6PR | c.599T>A p.V200D | Missense Mutation (SNP) | VAF 35/175 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); called by muse, mutect2, varscan2
- MARK2 | c.949G>C p.V317L | Missense Mutation (SNP) | VAF 35/186 reads (19%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- ME3 | c.515T>C p.L172P | Missense Mutation (SNP) | VAF 25/133 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- NEIL3 | c.797T>C p.F266S | Missense Mutation (SNP) | VAF 33/212 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- NRIP1 | c.749G>A p.R250K | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OR10G8 | c.395C>G p.T132S | Missense Mutation (SNP) | VAF 75/286 reads (26%) | SIFT tolerated (0.56); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- OXR1 | c.166_168del p.A56del (on ENST00000442977 / NM_001198532.1; = p.A55del on NM_018002.3) | In Frame Del (DEL) | VAF 49/248 reads (20%) | called by pindel, varscan2
- PCDHB8 | c.1294C>G p.L432V | Missense Mutation (SNP) | VAF 129/1312 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- PDZK1 | c.1420C>G p.L474V | Missense Mutation (SNP) | VAF 120/343 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.242); called by muse, mutect2, varscan2
- PGLYRP3 | c.985T>G p.L329V | Missense Mutation (SNP) | VAF 92/175 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.712); called by muse, mutect2, varscan2
- PRR19 | c.718_729del p.P240_Y243del | In Frame Del (DEL) | VAF 49/227 reads (22%) | called by mutect2, pindel, varscan2
- PSD | c.2208_2209del p.S736Rfs*36 | Frame Shift Del (DEL) | VAF 41/293 reads (14%) | called by mutect2, pindel, varscan2
- PYGL | c.1370_1373delinsG p.A457_K458delinsG | In Frame Del (DEL) | VAF 37/249 reads (15%) | called by pindel, varscan2*
- RHOT1 | c.658C>G p.P220A | Missense Mutation (SNP) | VAF 34/213 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- RPGR | c.1297G>T p.G433W | Missense Mutation (SNP) | VAF 58/132 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- RPL37A | c.199G>T p.G67C | Missense Mutation (SNP) | VAF 60/284 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- RYR3 | c.3958A>C p.I1320L | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2
- SAMSN1 | c.857T>A p.I286N | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- SERPIND1 | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 13/390 reads (3%) | SIFT tolerated (0.59); PolyPhen benign (0.036); called by muse, mutect2
- SETD2 | c.726_735del p.I243Yfs*5 | Frame Shift Del (DEL) | VAF 10/48 reads (21%) | called by mutect2, pindel, varscan2
- SLC17A6 | c.665C>A p.S222Y | Missense Mutation (SNP) | VAF 52/202 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SRBD1 | c.385A>T p.R129W | Missense Mutation (SNP) | VAF 147/560 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.715); called by muse, mutect2, varscan2
- SRRM2 | c.4268C>A p.S1423Y | Missense Mutation (SNP) | VAF 24/262 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- SRSF10 | c.65G>C p.R22T | Missense Mutation (SNP) | VAF 29/200 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- STAG2 | c.621_635del p.L207_V212delinsF | In Frame Del (DEL) | VAF 31/81 reads (38%) | called by mutect2, pindel
- TCP10L2 | c.195G>C p.Q65H | Missense Mutation (SNP) | VAF 55/326 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- TMEM74 | c.522_528del p.I174Mfs*17 | Frame Shift Del (DEL) | VAF 38/229 reads (17%) | called by mutect2, pindel, varscan2
- TNFRSF17 | c.302A>C p.N101T | Missense Mutation (SNP) | VAF 52/142 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.107); called by muse, varscan2
- TTC27 | c.387A>C p.Q129H | Missense Mutation (SNP) | VAF 86/279 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TTN | c.54723A>C p.R18241S (on ENST00000591111; = p.R10817S on NM_003319.4) | Missense Mutation (SNP) | VAF 48/235 reads (20%) | PolyPhen possibly damaging (0.523); called by muse, mutect2, varscan2
- UGGT1 | c.2173A>G p.I725V | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- UHRF1BP1L | c.2408C>T p.A803V | Missense Mutation (SNP) | VAF 25/137 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- WDR36 | c.1117A>T p.R373* | Nonsense Mutation (SNP) | VAF 107/500 reads (21%) | called by muse, mutect2, varscan2
- ZNF282 | c.820G>T p.D274Y | Missense Mutation (SNP) | VAF 52/163 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); called by muse, mutect2, varscan2
- ALDH3A1 | c.582G>A p.K194= | Silent (SNP) | VAF 92/476 reads (19%) | catalogued as rs1405748867; called by muse, mutect2, varscan2
- ANK2 | c.4503G>A p.P1501= | Silent (SNP) | VAF 34/132 reads (26%) | catalogued as rs779049064; called by muse, mutect2, varscan2
- APC | c.8046G>A p.V2682= | Silent (SNP) | VAF 25/166 reads (15%) | catalogued as rs1186346278; called by muse, mutect2, varscan2
- BAIAP3 | c.1674G>A p.S558= | Silent (SNP) | VAF 46/449 reads (10%) | catalogued as rs778541866, COSV50104113; called by muse, mutect2, varscan2
- BCL2A1 | c.492C>T p.I164= | Silent (SNP) | VAF 21/111 reads (19%) | catalogued as COSV51213282; called by muse, mutect2, varscan2
- CDIP1 | c.342A>C p.T114= | Silent (SNP) | VAF 264/739 reads (36%) | called by muse, mutect2, varscan2
- CROT | c.1140C>T p.I380= | Silent (SNP) | VAF 25/163 reads (15%) | called by muse, mutect2, varscan2
- CST9L | c.375C>A p.T125= | Silent (SNP) | VAF 53/288 reads (18%) | catalogued as COSV100980869; called by muse, mutect2, varscan2
- EFR3B | c.1638C>A p.L546= | Silent (SNP) | VAF 47/432 reads (11%) | called by muse, mutect2, varscan2
- ELN | c.2175C>T p.F725= (on ENST00000320399 / NM_001278939.1; = p.F692= on NM_000501.4) | Silent (SNP) | VAF 57/351 reads (16%) | called by muse, mutect2, varscan2
- FBXL13 | c.699C>G p.L233= | Silent (SNP) | VAF 13/330 reads (4%) | called by muse, mutect2
- ISLR | c.630C>T p.C210= | Silent (SNP) | VAF 22/200 reads (11%) | catalogued as rs145195184; called by muse, mutect2, varscan2
- LHX8 | c.1020C>A p.L340= | Silent (SNP) | VAF 42/282 reads (15%) | called by muse, mutect2, varscan2
- MBOAT1 | c.79C>T p.L27= | Silent (SNP) | VAF 16/276 reads (6%) | called by muse, mutect2
- MMAB | c.207T>C p.S69= | Silent (SNP) | VAF 114/518 reads (22%) | called by muse, mutect2, varscan2
- MMP19 | c.1458C>T p.T486= | Silent (SNP) | VAF 6/57 reads (11%) | called by muse, mutect2, varscan2
- MRPL2 | c.144C>A p.L48= | Silent (SNP) | VAF 35/174 reads (20%) | called by muse, mutect2, varscan2
- PCDHA12 | c.2034G>A p.T678= | Silent (SNP) | VAF 103/715 reads (14%) | catalogued as COSV56494590; called by muse, mutect2, varscan2
- POU4F1 | c.1104C>T p.R368= | Silent (SNP) | VAF 58/284 reads (20%) | catalogued as rs1318325630; called by muse, mutect2, varscan2
- PRDM8 | c.723G>T p.P241= | Silent (SNP) | VAF 46/239 reads (19%) | called by muse, varscan2
- RUNX1T1 | c.1131A>T p.V377= (on ENST00000265814 / NM_001198628.1; = p.V350= on NM_004349.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 85/461 reads (18%) | called by muse, mutect2, varscan2
- THAP12 | c.24C>T p.P8= | Silent (SNP) | VAF 52/229 reads (23%) | catalogued as rs989894015; called by muse, mutect2, varscan2
- WNK2 | c.474G>A p.A158= | Silent (SNP) | VAF 46/199 reads (23%) | catalogued as COSV52948443; called by muse, mutect2, varscan2
- ACTN1 | c.2361+233_2361+235del | Intron (DEL) | VAF 46/230 reads (20%) | called by mutect2, pindel, varscan2
- AL353804.7 | chrX:73851469 A>G | 3'Flank (SNP) | VAF 77/187 reads (41%) | called by muse, mutect2, varscan2
- AP000769.5 | chr11:65499318 del CTT | 5'Flank (DEL) | VAF 30/143 reads (21%) | called by pindel, varscan2
- CDK5RAP2 | c.4727-9T>A | Intron (SNP) | VAF 33/340 reads (10%) | catalogued as rs568636005; called by muse, mutect2
- CWF19L1 | c.-7C>G | 5'UTR (SNP) | VAF 42/223 reads (19%) | called by muse, mutect2, varscan2
- DUOXA1 | chr15:45117577 C>T | 3'Flank (SNP) | VAF 20/266 reads (8%) | called by muse, mutect2
- DYNC1H1 | c.10414-38G>A | Intron (SNP) | VAF 42/179 reads (23%) | catalogued as rs1372969031; called by muse, mutect2, varscan2
- GVINP1 | n.3190del | RNA (DEL) | VAF 35/136 reads (26%) | called by mutect2, pindel, varscan2
- HTR3A | c.*140C>T | 3'UTR (SNP) | VAF 69/414 reads (17%) | called by muse, mutect2, varscan2
- JMJD6 | chr17:76716714 T>A | 3'Flank (SNP) | VAF 36/215 reads (17%) | called by muse, mutect2, varscan2
- KTN1 | c.2173-2560G>T | Intron (SNP) | VAF 21/132 reads (16%) | catalogued as rs1041251349; called by muse, mutect2, varscan2
- LIPT2 | chr11:74497268 G>T | 5'Flank (SNP) | VAF 19/90 reads (21%) | called by muse, mutect2, varscan2
- MOSPD1 | c.-6_-3del | 5'UTR (DEL) | VAF 6/24 reads (25%) | called by mutect2, varscan2
- PAFAH1B1 | c.568+44G>A | Intron (SNP) | VAF 27/134 reads (20%) | called by muse, mutect2, varscan2
- PRKCG | c.-293T>C | 5'UTR (SNP) | VAF 28/79 reads (35%) | called by muse, mutect2, varscan2
- PTPRE | c.209+133G>A | Intron (SNP) | VAF 33/161 reads (20%) | called by muse, mutect2, varscan2
- TFAP2E | c.562+2402G>C | Intron (SNP) | VAF 50/248 reads (20%) | catalogued as rs192441123; called by muse, mutect2, varscan2
- TNFRSF10B | c.*2352T>C | 3'UTR (SNP) | VAF 64/246 reads (26%) | catalogued as rs898797876; called by muse, mutect2, varscan2
